Somatic mutation profile of tumor specimen TCGA-A6-5662-01A (aliquot TCGA-A6-5662-01A-01D-1650-10) from TCGA case TCGA-A6-5662, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Splenic flexure of colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 46.2 years (16,873 days).
Specimen TCGA-A6-5662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 705bbd96-675e-4e9c-9734-2f9bd4a0eebf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5662-10A (Blood Derived Normal), aliquot TCGA-A6-5662-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8781e443-82ea-4280-973c-8ec5f791b5d9

The open-access MAF lists 64 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 12, Nonsense Mutation 3, Frame Shift Del 2, 3'UTR 1, Frame Shift Ins 1, Intron 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 156/337 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 114/616 reads (19%) | catalogued as rs121913304, CM942039, COSV57296489; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.319T>G p.Y107D | Missense Mutation (SNP) | VAF 104/113 reads (92%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV52679423, COSV53179040; called by muse, mutect2, varscan2
- ACBD5 | c.1121A>T p.K374I (on ENST00000375888 / NM_001352568.1; = p.K365I on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 161/367 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV65520696; called by muse, mutect2, varscan2
- ADAMTS8 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs377242555; called by mutect2, varscan2
- ADGRL1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs202194686, COSV61565410, COSV61566057; called by muse, mutect2, varscan2
- APC | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 216/247 reads (87%) | catalogued as COSV57325414, COSV57354660, COSV57393116, COSV99964740; called by muse, mutect2, varscan2
- BBS7 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.865); catalogued as COSV52654031; called by muse, mutect2
- CALD1 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62647698; called by muse, mutect2, varscan2
- CBFA2T3 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51931032; called by muse, mutect2, varscan2
- CCBE1 | c.1032C>A p.D344E | Missense Mutation (SNP) | VAF 70/82 reads (85%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV67951022; called by muse, mutect2, varscan2
- CCR7 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.846); catalogued as rs753561165, COSV55850179; called by muse, mutect2, varscan2
- CD1B | c.966G>T p.W322C | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV63804890; called by muse, mutect2, varscan2
- COL26A1 | c.752G>A p.R251H (on ENST00000313669 / NM_001278563.3; = p.R249H on NM_133457.4) | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.083); catalogued as rs372045140; called by muse, mutect2, varscan2
- COL6A6 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs771370723, COSV62017401, COSV62033124; called by muse, mutect2, varscan2
- CS | c.1389dup p.K464* | Frame Shift Ins (INS) | VAF 134/410 reads (33%) | catalogued as rs1404206427; called by mutect2, varscan2
- DDX6 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 191/443 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50590538; called by muse, mutect2, varscan2
- DNAH17 | c.5771G>A p.R1924Q | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747374888, COSV67755491; called by muse, mutect2, varscan2
- DYNC2H1 | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV100517532, COSV62100057; called by muse, mutect2, varscan2
- FRMD6 | c.737C>T p.S246L (on ENST00000344768 / NM_001267046.2; = p.S238L on NM_152330.4) | Missense Mutation (SNP) | VAF 68/78 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs747022006, COSV61090032; called by muse, mutect2, varscan2
- GPR42 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1408849549; called by muse, mutect2, varscan2
- GRIK1 | c.1400A>T p.K467M | Missense Mutation (SNP) | VAF 95/118 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV58727421; called by muse, mutect2, varscan2
- IGSF11 | c.790G>A p.A264T (on ENST00000393775 / NM_001015887.3; = p.A263T on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/554 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs143207671; called by muse, mutect2, varscan2
- LCT | c.1894G>T p.A632S | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51554880; called by muse, mutect2, varscan2
- LRP1B | c.5032G>A p.A1678T | Missense Mutation (SNP) | VAF 116/290 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101261649; called by muse, varscan2
- METRN | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs773257021, COSV54799590; called by muse, mutect2, varscan2
- NCOA2 | c.1081A>G p.T361A | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV71763753; called by muse, mutect2, varscan2
- PCDH10 | c.819C>A p.N273K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766911892, COSV99994640; called by muse, mutect2, varscan2
- PCDHGA9 | c.1339G>C p.D447H | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54002511; called by muse, mutect2, varscan2
- PRTG | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs912500962, COSV66839676; called by muse, mutect2, varscan2
- RAN | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 36/411 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs201928609, COSV54563329; called by muse, mutect2
- REV3L | c.6007C>T p.R2003* | Nonsense Mutation (SNP) | VAF 37/297 reads (12%) | catalogued as COSV100725728; called by muse, mutect2, varscan2
- RIMS1 | c.4987T>A p.S1663T | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99330852; called by muse, mutect2
- RYR3 | c.4553G>A p.R1518H | Missense Mutation (SNP) | VAF 62/67 reads (93%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); catalogued as rs201954117, COSV66791324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHANK1 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV53258240; called by muse, mutect2, varscan2
- SIGLEC5 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 137/330 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.39); catalogued as rs776241864, COSV55780704; called by muse, mutect2, varscan2
- SPAG17 | c.1475G>A p.C492Y | Missense Mutation (SNP) | VAF 84/112 reads (75%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as rs1307623820, COSV60463915, COSV60464681; called by muse, mutect2, varscan2
- SPATA31D1 | c.1165T>A p.F389I | Missense Mutation (SNP) | VAF 126/274 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV61199324; called by muse, mutect2, varscan2
- SPOCK1 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV56460006; called by muse, mutect2, varscan2
- TBC1D8 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100964664; called by muse, mutect2
- TCTN3 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56449932; called by muse, mutect2, varscan2
- TRPC4 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 127/344 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59005747; called by muse, mutect2, varscan2
- TSHZ3 | c.2378C>A p.T793K | Missense Mutation (SNP) | VAF 78/164 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53678599; called by muse, mutect2, varscan2
- UBE4A | c.1740G>A p.M580I (on ENST00000252108 / NM_001204077.2; = p.M587I on NM_004788.4) | Missense Mutation (SNP) | VAF 96/209 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.163); catalogued as COSV52806187; called by muse, mutect2, varscan2
- UHRF1BP1 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51958919; called by muse, mutect2, varscan2
- ZFYVE28 | c.2581G>A p.G861R | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754212912, COSV52115363; called by muse, varscan2
- KRT15 | c.1204_1206del p.E402del | In Frame Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- PTAR1 | c.240del p.Q80Hfs*3 | Frame Shift Del (DEL) | VAF 92/260 reads (35%) | called by mutect2, pindel, varscan2
- STAG2 | c.3046del p.R1016Efs*11 | Frame Shift Del (DEL) | VAF 188/287 reads (66%) | called by mutect2, pindel, varscan2
- ALDH6A1 | c.1008G>A p.L336= | Silent (SNP) | VAF 39/43 reads (91%) | catalogued as COSV63247039; called by muse, mutect2, varscan2
- COL4A2 | c.4602G>T p.A1534= | Silent (SNP) | VAF 59/161 reads (37%) | catalogued as COSV64631948; called by muse, mutect2, varscan2
- EIF2B5 | c.1959G>A p.A653= (on ENST00000647909; = p.A645= on NM_003907.3) | Silent (SNP) | VAF 71/160 reads (44%) | catalogued as rs772251891, COSV56604845; called by muse, mutect2, varscan2
- MYT1 | c.3339G>A p.K1113= | Silent (SNP) | VAF 73/104 reads (70%) | catalogued as COSV60510912; called by muse, mutect2, varscan2
- PCBP3 | c.993C>T p.N331= | Silent (SNP) | VAF 35/43 reads (81%) | catalogued as rs114536865, COSV68409046; called by muse, mutect2, varscan2
- PHF2 | c.573C>T p.N191= | Silent (SNP) | VAF 65/108 reads (60%) | catalogued as rs780145036, COSV63682936; called by muse, mutect2, varscan2
- PTPRM | c.1110C>T p.L370= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV100160907; called by muse, mutect2, varscan2
- RUNX1T1 | c.1218C>T p.G406= (on ENST00000265814 / NM_001198628.1; = p.G379= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/174 reads (33%) | catalogued as rs778509217, COSV56157597; called by muse, mutect2, varscan2
- TSR1 | c.969C>T p.D323= | Silent (SNP) | VAF 91/217 reads (42%) | catalogued as rs776277475, COSV52160568; called by muse, mutect2, varscan2
- VWC2L | c.187T>C p.L63= | Silent (SNP) | VAF 26/239 reads (11%) | catalogued as COSV100436420; called by muse, mutect2, varscan2
- ZFC3H1 | c.4155T>A p.S1385= | Silent (SNP) | VAF 76/93 reads (82%) | catalogued as COSV66434815; called by muse, mutect2, varscan2
- ZNF143 | c.294G>A p.G98= | Silent (SNP) | VAF 80/170 reads (47%) | catalogued as COSV100218061; called by muse, varscan2
- CDH11 | c.1895-620C>A | Intron (SNP) | VAF 49/112 reads (44%) | catalogued as COSV51758140; called by muse, mutect2, varscan2
- CDKN1B | c.*80T>A | 3'UTR (SNP) | VAF 102/217 reads (47%) | catalogued as COSV99964085; called by muse, mutect2, varscan2
- PKD1L2 | n.1304C>T | RNA (SNP) | VAF 41/77 reads (53%) | catalogued as rs755564356; called by muse, mutect2, varscan2
